Somatic mutation profile of tumor specimen HCM-CSHL-0853-C56-07A (aliquot HCM-CSHL-0853-C56-07A-11D-A881-36) from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-07A: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf9f3faf-536b-411f-ba89-dae541402eac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b39ac41-34c4-417f-b5b3-9b46f2956903

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 88/207 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPL | c.1434C>G p.N478K | Missense Mutation (SNP) | VAF 27/951 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100876203; called by muse, mutect2
- ATP2B3 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 242/817 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1557013353; called by muse, mutect2, varscan2
- C2CD2L | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 209/993 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs940210543; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 190/358 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CNOT1 | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55320287; called by muse, mutect2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- FAM160A2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 24/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768160220; called by muse, mutect2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- MAPK14 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs760295301; called by muse, mutect2, varscan2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/412 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- TICAM1 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs774037288, COSV99941144, COSV99941160; called by muse, mutect2
- CFH | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 91/358 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 31/738 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- NSD1 | c.6195T>A p.N2065K | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLXNA3 | c.2511C>A p.C837* | Nonsense Mutation (SNP) | VAF 191/867 reads (22%) | called by muse, mutect2, varscan2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 174/354 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RCN3 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 215/473 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 84/325 reads (26%) | called by muse, mutect2, varscan2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 189/571 reads (33%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.867C>T p.N289= | Silent (SNP) | VAF 176/377 reads (47%) | catalogued as rs374654639; called by muse, mutect2, varscan2
- NCAPH | c.687C>T p.N229= | Silent (SNP) | VAF 93/294 reads (32%) | catalogued as rs760742546; called by muse, mutect2, varscan2
- NR0B2 | c.138C>T p.P46= | Silent (SNP) | VAF 165/300 reads (55%) | catalogued as rs370821222; called by muse, mutect2, varscan2
- SHOC1 | c.2052G>A p.L684= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 144/514 reads (28%) | called by mutect2, pindel, varscan2
